Somatic mutation profile of tumor specimen ALCH-B3EU-TTP1-A (aliquot ALCH-B3EU-TTP1-A-2-0-D-A78R-36) from ALCHEMIST case ALCH-B3EU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.6 years (27,235 days).
Specimen ALCH-B3EU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a79deca-9888-409d-8276-d68ac3171d01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3EU-NB1-A (Blood Derived Normal), aliquot ALCH-B3EU-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/186d2dcd-7d92-42fb-b285-1a7c804b8c91

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 11, Nonsense Mutation 9, Intron 2, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 28/356 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- DNPEP | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56111178; called by muse, mutect2
- FBLN7 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753743458, COSV55615817; called by mutect2, varscan2
- KCNMB1 | c.233G>A p.W78* | Nonsense Mutation (SNP) | VAF 53/712 reads (7%) | catalogued as rs778187074; called by muse, mutect2
- ME2 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58422563; called by muse, mutect2
- RGL1 | c.2089G>T p.E697* (on ENST00000360851 / NM_001297672.2; = p.E732* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/468 reads (7%) | catalogued as COSV100487710; called by muse, mutect2
- SMARCD1 | c.870C>A p.Y290* | Nonsense Mutation (SNP) | VAF 17/152 reads (11%) | catalogued as rs1189341542; called by muse, mutect2, varscan2
- TRAV3 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 61/874 reads (7%) | catalogued as rs751471202; called by muse, mutect2
- ZNF831 | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV64038358; called by muse, mutect2
- AEBP2 | c.1383G>C p.W461C | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- AJAP1 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- BRINP3 | c.1955T>C p.I652T | Missense Mutation (SNP) | VAF 40/691 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2
- CFAP92 | c.2364C>A p.H788Q | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2
- COL4A1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 54/792 reads (7%) | called by muse, mutect2
- EHMT2 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.088); called by muse, mutect2
- FAT2 | c.1530C>A p.Y510* | Nonsense Mutation (SNP) | VAF 28/502 reads (6%) | called by muse, mutect2
- HK3 | c.1746C>A p.D582E | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- IGKV1-12 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 40/1032 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2
- LAMB1 | c.2874T>A p.C958* | Nonsense Mutation (SNP) | VAF 21/333 reads (6%) | called by muse, mutect2
- MMP9 | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 36/750 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NES | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by mutect2, varscan2
- NOTCH2 | c.2094C>G p.I698M | Missense Mutation (SNP) | VAF 30/528 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); called by muse, mutect2
- NUP210 | c.3209C>G p.S1070* | Nonsense Mutation (SNP) | VAF 10/151 reads (7%) | called by muse, mutect2
- PPP1R37 | c.1846G>T p.G616W | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2
- SLC7A9 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 33/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA7 | c.3939T>C p.H1313= | Silent (SNP) | VAF 9/217 reads (4%) | called by muse, mutect2
- ARHGAP39 | c.1788C>T p.P596= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as rs1159900182, COSV99432519; called by muse, mutect2
- CD2AP | c.45T>C p.D15= | Silent (SNP) | VAF 26/404 reads (6%) | called by muse, mutect2
- F2 | c.114C>T p.L38= | Silent (SNP) | VAF 31/314 reads (10%) | catalogued as COSV61316652; called by muse, mutect2, varscan2
- FAM200B | c.936A>G p.K312= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- MS4A6A | c.111G>C p.L37= | Silent (SNP) | VAF 44/514 reads (9%) | called by muse, mutect2
- PCDHB4 | c.633C>T p.L211= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as COSV52019723; called by muse, mutect2
- PLCD4 | c.2190C>T p.R730= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs772560475; called by muse, mutect2
- TCF21 | c.255C>T p.N85= | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as rs984449296, COSV52818555; called by muse, mutect2, varscan2
- TOX2 | c.1137G>T p.P379= (on ENST00000358131 / NM_001098798.2; = p.P355= on NM_032883.3) | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ZFHX2 | c.6417C>T p.G2139= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- ABCA13 | c.*31C>T | 3'UTR (SNP) | VAF 29/558 reads (5%) | called by muse, mutect2
- AC133561.1 | n.2000G>T | RNA (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- COG4 | c.1062-48C>G | Intron (SNP) | VAF 16/248 reads (6%) | catalogued as rs1333682167; called by muse, mutect2
- NBPF11 | c.-548-2813G>C | Intron (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- NXF5 | n.1480C>A | RNA (SNP) | VAF 31/281 reads (11%) | called by muse, mutect2, varscan2
